Somatic mutation profile of tumor specimen ALCH-B04K-TTP1-A (aliquot ALCH-B04K-TTP1-A-3-0-D-A679-36) from ALCHEMIST case ALCH-B04K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.8 years (26,583 days).
Specimen ALCH-B04K-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 498a694f-756d-43d1-8c15-8f49d671be1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B04K-NB1-A (Blood Derived Normal), aliquot ALCH-B04K-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18c04c8b-6b8b-490f-964b-fb0f6b0c7b42

The open-access MAF lists 234 somatic variants for this specimen: 166 protein-altering or splice-affecting, 45 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 45, Nonsense Mutation 14, Intron 12, Splice Site 5, Frame Shift Del 4, 5'UTR 3, RNA 3, Splice Region 2, 3'Flank 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 43/129 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARMCX1 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65705078; called by muse, mutect2
- BCORL1 | c.303C>A p.Y101* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV54405404; called by mutect2, varscan2
- CEP135 | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 46/381 reads (12%) | catalogued as rs1397337217; called by muse, mutect2, varscan2
- CNTNAP2 | c.1478G>C p.G493A | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62213362; called by muse, mutect2
- CNTNAP5 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70472881, COSV70490958; called by muse, mutect2
- CPS1 | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761218425; called by muse, mutect2, varscan2
- CUBN | c.7646C>T p.T2549M | Missense Mutation (SNP) | VAF 46/410 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs537292240; ClinVar: not provided; called by muse, mutect2, varscan2
- DNER | c.766C>G p.R256G | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV59166052; called by muse, mutect2, varscan2
- EDA | c.656del p.P219Lfs*61 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as COSV65785168; called by mutect2, pindel, varscan2
- EFNA5 | c.322C>G p.P108A | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV60958713; called by muse, mutect2
- EIF4G2 | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as rs1308273204, COSV101150981; called by muse, mutect2
- ELMO1 | c.1974C>A p.D658E | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as COSV60299499; called by muse, mutect2
- EPHA3 | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV60728920; called by muse, mutect2, varscan2
- FAM3B | c.179G>T p.R60M | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100783710; called by muse, mutect2, varscan2
- FANCG | c.1430G>T p.S477I | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs766157946; called by muse, mutect2
- FGF14 | c.382A>G p.N128D | Missense Mutation (SNP) | VAF 32/560 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV65961419; called by muse, mutect2
- FSD1 | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55698350; called by muse, mutect2
- HMGCLL1 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs764492712, COSV51446547; called by muse, mutect2, varscan2
- HPS1 | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139951191; called by muse, mutect2, varscan2
- IGLV1-44 | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs542978656; called by muse, mutect2
- INSC | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as rs946093233, COSV65411188, COSV65411351; called by muse, mutect2, varscan2
- KDF1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 14/130 reads (11%) | catalogued as rs754712166; called by muse, mutect2
- KRT32 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs775905231; called by muse, mutect2, varscan2
- MAX | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 63/486 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs876659562, COSV52417087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEFV | c.852T>A p.D284E | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs780239624; called by muse, mutect2, varscan2
- MRPS5 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55533073; called by muse, mutect2, varscan2
- MUC16 | c.32956G>A p.G10986R | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV67493917; called by muse, mutect2
- NLRP14 | c.2662A>T p.S888C | Missense Mutation (SNP) | VAF 70/527 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1197484839; called by muse, mutect2, varscan2
- NOS1 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV57615072; called by muse, mutect2, varscan2
- OTULINL | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as rs568811741; called by muse, mutect2, varscan2
- PCDH11X | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 92/700 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.762); catalogued as COSV53446770; called by muse, mutect2, varscan2
- RPS6KC1 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1446575403, COSV65302083; called by muse, mutect2
- S100A7A | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1203244847; called by muse, mutect2
- SAGE1 | c.1309G>C p.V437L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV61013462; called by muse, mutect2, varscan2
- SBF1 | c.3601C>T p.R1201W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1232684184, COSV104421052; called by muse, mutect2
- SENP5 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.007); catalogued as COSV100052256; called by muse, mutect2
- SI | c.3455A>G p.Y1152C | Missense Mutation (SNP) | VAF 55/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52282665; called by muse, mutect2, varscan2
- SLC35D1 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs953689589; called by muse, mutect2, varscan2
- SMARCAD1 | c.1716G>C p.K572N | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1409646546, COSV62775231; called by mutect2, varscan2
- SUCNR1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100751780; called by muse, mutect2
- TCN1 | c.543C>A p.S181R | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as rs756196612; called by muse, mutect2
- TGFBR1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs757374917, CM112279, COSV66624788; called by muse, mutect2
- TMEM200A | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51656108; called by muse, mutect2, varscan2
- TMEM64 | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV69127686; called by muse, mutect2, varscan2
- TP53 | c.767C>A p.T256K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM951232, COSV52837901, COSV52987484, COSV53189701, COSV53518652; called by muse, mutect2, varscan2
- TRPC6 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 31/450 reads (7%) | catalogued as COSV60256010; called by muse, mutect2
- TRPM6 | c.3733A>T p.T1245S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV62516023; called by mutect2, varscan2
- UTP20 | c.8345C>T p.A2782V | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1261541847, COSV55379880; called by muse, mutect2, varscan2
- XIRP2 | c.8249C>G p.S2750C (on ENST00000628543; = p.S2925C on NM_152381.6) | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV54691861, COSV54713165; called by muse, mutect2
- ZBTB3 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67360884; called by muse, mutect2
- ZNF718 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV101210263; called by muse, mutect2
- ABCA12 | c.1061A>C p.Q354P (on ENST00000272895 / NM_173076.3; = p.Q36P on NM_015657.3) | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2
- ABCC9 | c.1852A>G p.S618G | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- ACAN | c.311T>A p.V104D | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ACTB | c.475dup p.V159Gfs*29 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- ACTR3B | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ADAMTS15 | c.2466C>A p.H822Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.4292G>T p.R1431M | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRB3 | c.4293G>T p.R1431S | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADIPOQ | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- AK5 | c.1046A>T p.D349V (on ENST00000354567 / NM_174858.3; = p.D323V on NM_012093.4) | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- AK9 | c.1340C>A p.A447E | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANK2 | c.10137G>A p.M3379I | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGEF2 | c.2693G>A p.W898* | Nonsense Mutation (SNP) | VAF 25/426 reads (6%) | called by muse, mutect2
- ARMC3 | c.1277C>A p.A426D | Missense Mutation (SNP) | VAF 45/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BRPF3 | c.1500G>T p.M500I | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- CACNA1B | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- CACNA1C | c.4756C>T p.R1586W | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- CARNMT1 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLK2 | c.994A>T p.T332S (on ENST00000368361 / NM_001294339.2; = p.T331S on NM_003993.4) | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CMYA5 | c.10854G>A p.M3618I | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL11A2 | c.2267G>T p.R756M (on ENST00000341947 / NM_080680.3; = p.R649M on NM_080679.2) | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL4A6 | c.2417C>A p.P806Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); called by muse, mutect2
- DCSTAMP | c.820A>T p.R274W | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ERVV-1 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- EYS | c.3087C>A p.D1029E | Missense Mutation (SNP) | VAF 12/353 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2
- FANCG | c.1431C>T p.S477= | Splice Region (SNP) | VAF 18/275 reads (7%) | called by muse, mutect2
- FBXO16 | c.741A>C p.G247= | Splice Region (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2
- FCSK | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2
- FGD5 | c.2156C>A p.P719H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXK2 | c.762+2_762+7del p.X254_splice | Splice Site (DEL) | VAF 19/169 reads (11%) | called by mutect2, pindel, varscan2
- GNPDA2 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.031); called by muse, mutect2
- GRIN2A | c.4376G>T p.S1459I | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIN2B | c.3659C>A p.S1220Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GYS2 | c.679-2A>T p.X227_splice | Splice Site (SNP) | VAF 24/434 reads (6%) | called by muse, mutect2
- HCFC1 | c.3874C>G p.P1292A | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IFI30 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.096); called by muse, mutect2
- ITGA8 | c.1445+1G>T p.X482_splice | Splice Site (SNP) | VAF 36/337 reads (11%) | called by muse, mutect2, varscan2
- ITGA8 | c.1445G>T p.R482I | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JHY | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- KALRN | c.5588G>C p.R1863P (on ENST00000360013 / NM_001024660.4; = p.R166P on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2
- KDR | c.3569C>G p.S1190C | Missense Mutation (SNP) | VAF 13/418 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- KIF20B | c.3303A>T p.R1101S (on ENST00000371728 / NM_001284259.2; = p.R1061S on NM_016195.4) | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- KIR2DL1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 16/622 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2
- KLK3 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KRTAP4-6 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- LIPK | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- LMOD3 | c.519G>C p.E173D | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.8663-2A>G p.X2888_splice | Splice Site (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- LRRC8C | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 10/313 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by muse, mutect2
- MAP3K12 | c.266A>T p.E89V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MGA | c.6618G>T p.K2206N (on ENST00000219905 / NM_001164273.1; = p.K1997N on NM_001080541.2) | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.991); called by muse, mutect2
- MORF4L2 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- MRC1 | c.1436A>T p.E479V | Missense Mutation (SNP) | VAF 48/434 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MSANTD4 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUC16 | c.39745G>A p.G13249R | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.996); called by muse, mutect2
- MUC7 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 60/468 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- MYCBP2 | c.7630C>G p.P2544A (on ENST00000357337; = p.P2582A on NM_015057.5) | Missense Mutation (SNP) | VAF 52/339 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH6 | c.2108G>C p.G703A | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- NBPF11 | c.148_155del p.F50Qfs*9 | Frame Shift Del (DEL) | VAF 38/344 reads (11%) | called by mutect2, pindel
- NCKAP5 | c.4402del p.L1468Sfs*53 | Frame Shift Del (DEL) | VAF 19/163 reads (12%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.3709G>T p.G1237C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- NOVA2 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPAP1 | c.2964G>T p.M988I | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- NRXN3 | c.2153C>A p.A718D (on ENST00000335750 / NM_001330195.2; = p.A345D on NM_004796.6) | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NRXN3 | c.2155T>A p.Y719N (on ENST00000335750 / NM_001330195.2; = p.Y346N on NM_004796.6) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- NUGGC | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.159); called by muse, mutect2
- OGFOD1 | c.1529T>A p.L510Q | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- OR51L1 | c.374T>C p.F125S | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR5B17 | c.338T>A p.L113* | Nonsense Mutation (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- OR5M10 | c.623C>A p.S208* | Nonsense Mutation (SNP) | VAF 34/350 reads (10%) | called by muse, mutect2
- OR7D4 | c.324del p.G109Efs*9 | Frame Shift Del (DEL) | VAF 28/220 reads (13%) | called by mutect2, varscan2
- OR8H2 | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- OR8H2 | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2
- P2RY10 | c.420G>T p.R140S | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PACSIN2 | c.331A>T p.K111* | Nonsense Mutation (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- PADI6 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- PCDH12 | c.2659A>T p.T887S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.024); called by muse, mutect2
- PCDH15 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX2 | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- PNISR | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 36/474 reads (8%) | called by muse, mutect2
- PPP1R2B | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 31/477 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2
- PPP4R3C | c.1232A>T p.D411V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2
- PRAMEF11 | c.205A>T p.R69W | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- PRSS58 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- RHAG | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 20/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- RNF115 | c.754A>T p.S252C | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RNF165 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- RPS15A | c.226A>T p.S76C | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.121); called by muse, mutect2
- RPS6KA6 | c.631C>A p.H211N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, varscan2
- RYR2 | c.1379T>A p.I460N | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SEPTIN14 | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SGCA | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SIRPB1 | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.043); called by muse, mutect2
- SLC13A5 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SLIT3 | c.2990C>A p.P997Q | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.223); called by muse, varscan2
- SMG7 | c.1007-4_1008delinsTTTTTT p.X336_splice | Splice Site (ONP) | VAF 9/96 reads (9%) | called by mutect2*, pindel
- SND1 | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPTA1 | c.3737C>T p.A1246V | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SRFBP1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SRP54 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- TENT5D | c.677G>T p.R226M | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TEX13C | c.1315A>T p.S439C | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TG | c.362A>C p.Q121P | Missense Mutation (SNP) | VAF 59/469 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TLE1 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- TRIML1 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.541); called by mutect2, varscan2
- UBASH3A | c.1858C>A p.L620M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC80 | c.7483T>C p.S2495P | Missense Mutation (SNP) | VAF 21/474 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- WDR44 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZFHX4 | c.5263G>C p.G1755R | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ZIM2 | c.1157G>T p.C386F | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ZNF280A | c.671T>G p.V224G | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2
- ZNF536 | c.3528G>C p.E1176D | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2
- ZNF571 | c.1441A>T p.K481* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- ZNF573 | c.979A>G p.K327E (on ENST00000536220 / NM_001172692.1; = p.K269E on NM_152360.3) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- CACNA1S | c.108G>C p.L36= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- CALHM6 | c.144C>T p.N48= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, varscan2
- CES4A | c.1128C>T p.I376= | Silent (SNP) | VAF 26/179 reads (15%) | catalogued as COSV58652294; called by muse, mutect2, varscan2
- CLGN | c.1182A>G p.P394= | Silent (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- COL5A2 | c.3768G>T p.A1256= | Silent (SNP) | VAF 61/543 reads (11%) | catalogued as COSV66407627, COSV66414160; called by muse, mutect2, varscan2
- CPSF1 | c.36C>A p.T12= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1198340200; called by muse, mutect2, varscan2
- DST | c.12180C>G p.L4060= (on ENST00000361203 / NM_001374722.1; = p.L1648= on NM_015548.5) | Silent (SNP) | VAF 23/546 reads (4%) | catalogued as rs762349901, COSV55035601; called by muse, mutect2
- DZANK1 | c.1329C>T p.G443= (on ENST00000262547 / NM_001099407.1; = p.G250= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/527 reads (4%) | catalogued as rs900725260; called by muse, mutect2
- FAM135B | c.3726G>T p.T1242= | Silent (SNP) | VAF 30/292 reads (10%) | catalogued as COSV52725827, COSV52735078; called by muse, mutect2, varscan2
- FBH1 | c.810C>T p.V270= (on ENST00000362091 / NM_178150.3; = p.V321= on NM_032807.4) | Silent (SNP) | VAF 22/323 reads (7%) | called by muse, mutect2
- FBRSL1 | c.1809C>T p.Y603= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, varscan2
- FBXL4 | c.1269C>T p.A423= | Silent (SNP) | VAF 18/353 reads (5%) | called by muse, mutect2
- GPHN | c.1101C>T p.P367= (on ENST00000315266 / NM_001377519.1; = p.P400= on NM_020806.5) | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- GPR156 | c.255C>A p.P85= | Silent (SNP) | VAF 39/248 reads (16%) | called by muse, mutect2, varscan2
- LSP1 | c.573C>T p.P191= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- LYPD6 | c.36C>T p.L12= | Silent (SNP) | VAF 31/179 reads (17%) | called by muse, mutect2, varscan2
- MARCO | c.123G>T p.G41= | Silent (SNP) | VAF 16/144 reads (11%) | called by muse, varscan2
- MBTD1 | c.756T>C p.Y252= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs138758456; called by muse, mutect2, varscan2
- MED6 | c.378T>A p.I126= | Silent (SNP) | VAF 10/285 reads (4%) | called by muse, mutect2
- MKKS | c.690A>G p.L230= | Silent (SNP) | VAF 18/430 reads (4%) | called by muse, mutect2
- MS4A2 | c.441C>A p.I147= | Silent (SNP) | VAF 31/394 reads (8%) | catalogued as COSV54013839; called by muse, mutect2
- MUC12 | c.12372T>A p.P4124= (on ENST00000379442; = p.P3981= on NM_001164462.1) | Silent (SNP) | VAF 23/392 reads (6%) | called by muse, mutect2
- NAV3 | c.957T>A p.P319= | Silent (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- NPHS1 | c.40C>T p.L14= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1490992404; called by muse, mutect2, varscan2
- OR4K15 | c.636C>A p.A212= (on ENST00000305051; = p.A188= on NM_001005486.1) | Silent (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- OR6C74 | c.879A>G p.K293= | Silent (SNP) | VAF 16/232 reads (7%) | catalogued as COSV59606175; called by muse, mutect2
- PCDH11X | c.33G>T p.A11= | Silent (SNP) | VAF 33/439 reads (8%) | catalogued as rs201918535, COSV53496716; called by muse, mutect2
- PCDHGA1 | c.1815C>A p.S605= | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- PCSK1 | c.729C>T p.G243= | Silent (SNP) | VAF 37/285 reads (13%) | called by muse, mutect2, varscan2
- POLQ | c.687G>T p.L229= | Silent (SNP) | VAF 30/299 reads (10%) | called by muse, mutect2, varscan2
- RYR3 | c.10926C>A p.P3642= (on ENST00000389232; = p.P3643= on NM_001036.6) | Silent (SNP) | VAF 16/187 reads (9%) | catalogued as COSV66801857; called by muse, mutect2
- SCN10A | c.5019A>T p.T1673= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- SERPINA1 | c.1026C>G p.L342= | Silent (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- SLC22A13 | c.972G>C p.L324= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs769014812; called by muse, mutect2, varscan2
- SNRNP200 | c.3783G>A p.P1261= | Silent (SNP) | VAF 44/317 reads (14%) | catalogued as rs770679567; called by muse, mutect2, varscan2
- SOHLH1 | c.756C>A p.T252= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- SPATA13 | c.1623T>C p.F541= | Silent (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- SPTB | c.1440C>T p.A480= | Silent (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- SRP54 | c.1068G>T p.G356= | Silent (SNP) | VAF 20/176 reads (11%) | called by mutect2, varscan2
- SYTL5 | c.477C>T p.T159= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as COSV52905600; called by muse, mutect2, varscan2
- TBC1D3F | c.87G>T p.G29= | Silent (SNP) | VAF 14/72 reads (19%) | called by mutect2, varscan2
- TENM2 | c.459C>A p.T153= | Silent (SNP) | VAF 36/390 reads (9%) | catalogued as COSV101595489; called by muse, mutect2
- TPTE2 | c.753G>T p.R251= (on ENST00000400230 / NM_199254.2; = p.R174= on NM_130785.3) | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.639G>T p.L213= | Silent (SNP) | VAF 12/167 reads (7%) | catalogued as COSV57629786; called by muse, mutect2
- ZNF449 | c.1458A>T p.T486= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- ADGRL2 | c.3625+279G>A | Intron (SNP) | VAF 23/219 reads (11%) | catalogued as COSV99587755; called by muse, mutect2, varscan2
- AP3B2 | c.1056-20C>T | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- ASIC4 | c.1018+469G>A | Intron (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- CD70 | chr19:6583397 G>A | 3'Flank (SNP) | VAF 12/113 reads (11%) | catalogued as rs1002266268; called by muse, mutect2, varscan2
- CTSC | c.318+8537G>T | Intron (SNP) | VAF 26/330 reads (8%) | called by muse, mutect2
- FAM13A | c.759+11T>G | Intron (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2, varscan2
- FAM90A25P | n.751C>A | RNA (SNP) | VAF 30/288 reads (10%) | called by muse, varscan2
- HBE1 | c.-267+102073C>G | Intron (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- IGFN1 | c.1241+2917G>T | Intron (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- JAKMIP2 | c.-178C>A | 5'UTR (SNP) | VAF 17/336 reads (5%) | called by muse, mutect2
- KIFC3 | c.*189G>T | 3'UTR (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- LITAF | chr16:11547848 T>A | 3'Flank (SNP) | VAF 39/526 reads (7%) | called by muse, mutect2
- NLRP12 | c.-1del | 5'UTR (DEL) | VAF 4/38 reads (11%) | catalogued as COSV60756305; called by mutect2, varscan2
- PIPSL | n.905C>T | RNA (SNP) | VAF 15/269 reads (6%) | called by muse, mutect2
- PPT2 | chr6:32153549 G>C | 5'Flank (SNP) | VAF 6/125 reads (5%) | called by muse, mutect2
- RNF217-AS1 | n.2200C>A | RNA (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- SERPINA1 | c.1065+34G>T | Intron (SNP) | VAF 14/181 reads (8%) | catalogued as COSV100872168; called by muse, mutect2
- SERPINA7 | c.1045-29G>A | Intron (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- SGCZ | c.40-298560G>T | Intron (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2
- SGCZ | c.40-298562G>T | Intron (SNP) | VAF 13/111 reads (12%) | catalogued as rs913343525; called by muse, mutect2
- TMEM18 | c.-8C>T | 5'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- ZNF423 | c.*9T>A | 3'UTR (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- ZNF451 | c.186+2431G>T | Intron (SNP) | VAF 21/200 reads (11%) | catalogued as rs1156764665; called by muse, mutect2, varscan2
